Somatic mutation profile of tumor specimen TCGA-QF-A5YS-01A (aliquot TCGA-QF-A5YS-01A-11D-A31U-09) from TCGA case TCGA-QF-A5YS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 57.1 years (20,841 days).
Specimen TCGA-QF-A5YS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3de7572-a319-4cf8-94a6-f4410d201cb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QF-A5YS-10A (Blood Derived Normal), aliquot TCGA-QF-A5YS-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6db64732-3ac0-44f6-b0cb-ab0bfd1948e6

The open-access MAF lists 1,780 somatic variants for this specimen: 1,402 protein-altering or splice-affecting, 337 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,151, Silent 337, Nonsense Mutation 217, Splice Site 15, Intron 15, RNA 14, Splice Region 9, Frame Shift Ins 6, 5'Flank 5, 3'Flank 3, Frame Shift Del 3, 5'UTR 2.

Variants (750 of 1,780; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs376926391, CM082466, CM122251; ClinVar: pathogenic; called by muse, mutect2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATM | c.4852C>T p.R1618* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as rs762083530, CM983653, COSV53726137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.10951C>T p.R3651* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as rs769929539, COSV59438495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAL | c.733C>T p.R245* (on ENST00000269162 / NM_001142339.3; = p.R322* on NM_182978.4) | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs1252185897, CM135135, COSV52323513; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs1131691999, CM013729, CM013730, COSV55691267; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 36/83 reads (43%) | hotspot (GDC flag); catalogued as rs63751411, CM981314, COSV51876952; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5899C>T p.R1967* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs376764423, CM138861; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYPN | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205457, COSV62733066; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 12/20 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- RB1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as rs121913296, CM961221, COSV57300832; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SIN3A | c.3310C>T p.R1104* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as rs879255621, COSV64581642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPRED1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518150, COSV54438109, COSV54438678; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TCF4 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as rs878853149, CM120282, COSV61890253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TG | c.4588C>T p.R1530* | Nonsense Mutation (SNP) | VAF 31/58 reads (53%) | catalogued as rs121912646, CM930703; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs869025531, CM1210056, COSV65109013, COSV65110174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.738G>T p.M246I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52735934, COSV52772732, COSV53038458, COSV53481758; called by muse, varscan2
- A2M | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs369574498; called by mutect2, varscan2
- AADACL3 | c.1184G>T p.R395I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs780900877, COSV60200400; called by muse, mutect2, varscan2
- AARS1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV55747820; called by muse, mutect2, varscan2
- ABCA10 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99288766; called by muse, mutect2, varscan2
- ABCA12 | c.1952A>G p.Y651C (on ENST00000272895 / NM_173076.3; = p.Y333C on NM_015657.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99790361; called by muse, mutect2, varscan2
- ABCA13 | c.12826G>A p.D4276N | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs765749513, COSV68943080; called by muse, mutect2, varscan2
- ABCA2 | c.2270T>C p.I757T (on ENST00000614293; = p.I727T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV55799055; called by muse, mutect2, varscan2
- ABCA3 | c.4964G>A p.R1655H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs148823458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as rs138416476, COSV52637314; called by muse, mutect2, varscan2
- ABCA9 | c.4618C>A p.P1540T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100383196; called by muse, mutect2, varscan2
- ABCB4 | c.2765A>G p.K922R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99710629; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB5 | c.2843G>A p.R948Q (on ENST00000404938 / NM_001163941.2; = p.R503Q on NM_178559.6) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.178); catalogued as rs200559589, COSV51720897; called by muse, mutect2, varscan2
- ABCC1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1476099956, COSV100579778; called by muse, mutect2
- ABCC2 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as rs748245551, COSV64970648, COSV64970740; called by muse, mutect2, varscan2
- ABCC2 | c.4285G>A p.E1429K | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs754646220, COSV64985593; called by muse, mutect2, varscan2
- ABCC4 | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV65313328; called by muse, mutect2, varscan2
- ABCF3 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777071943, COSV99490666; called by muse, mutect2, varscan2
- ABHD17B | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1263740394, COSV61009064; called by muse, mutect2, varscan2
- ABL2 | c.835G>A p.D279N (on ENST00000502732 / NM_007314.4; = p.D264N on NM_005158.5) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1435047034, COSV100773131; called by muse, mutect2
- AC105001.2 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV100134878; called by muse, mutect2, varscan2
- AC244197.3 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.249); catalogued as rs370125505, COSV100558049; called by muse, mutect2, varscan2
- ACAP1 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV50138742, COSV99341745; called by muse, mutect2, varscan2
- ACBD7 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as rs1382163370, COSV62252310, COSV62252316; called by muse, mutect2, varscan2
- ACO2 | c.1402A>G p.I468V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as rs1485743796, COSV99347486; called by muse, mutect2, varscan2
- ACP3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475900, COSV60485052; called by muse, mutect2, varscan2
- ACSBG2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.567); catalogued as rs751060741, COSV53123875; called by muse, mutect2, varscan2
- ACSM3 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99184594; called by muse, mutect2, varscan2
- ACTA1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as COSV100796753; called by muse, mutect2, varscan2
- ACTR10 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.724); catalogued as COSV54299877; called by muse, mutect2, varscan2
- ACTR8 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as COSV51635989; called by muse, mutect2, varscan2
- ADAM18 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752576579, COSV55848661, COSV99695695; called by mutect2, varscan2
- ADAM22 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs370014529, COSV55969068; called by muse, mutect2, varscan2
- ADAM23 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100007905; called by muse, mutect2, varscan2
- ADAM7 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV99444176; called by muse, mutect2, varscan2
- ADAM7 | c.1657G>T p.D553Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV51536365, COSV51538629; called by muse, mutect2, varscan2
- ADAMTS9 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as rs1193053630, COSV55789599; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.420A>C p.E140D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100416556; called by muse, mutect2, varscan2
- ADGRG4 | c.3101C>A p.S1034Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99795789; called by muse, mutect2, varscan2
- ADGRG4 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV99795793; called by muse, mutect2, varscan2
- ADGRV1 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs762744741, COSV67980221; called by muse, mutect2, varscan2
- ADGRV1 | c.15106G>A p.D5036N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867504287, COSV67991999; called by muse, mutect2, varscan2
- ADRA1D | c.1152C>A p.F384L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV101063047; called by muse, mutect2, varscan2
- AFM | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV99888906; called by muse, mutect2, varscan2
- AGAP1 | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100365605; called by muse, mutect2, varscan2
- AGAP6 | c.1934C>T p.S645F (on ENST00000374056 / NM_001365867.1; = p.S668F on NM_001077665.2) | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100929094; called by mutect2, varscan2
- AGPS | c.451A>C p.N151H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as COSV99931431; called by muse, mutect2, varscan2
- AGTPBP1 | c.3472G>T p.D1158Y (on ENST00000357081 / NM_001330701.2; = p.D1118Y on NM_015239.2) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs762041915, COSV100429881; called by muse, mutect2, varscan2
- AGTR2 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100903590; called by muse, mutect2, varscan2
- AHCYL2 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV100273486; called by muse, mutect2, varscan2
- AHNAK | c.15621G>T p.K5207N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.709); catalogued as COSV99947957; called by muse, mutect2, varscan2
- AHNAK2 | c.1963A>C p.K655Q | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.107); catalogued as COSV100317863, COSV60911076; called by muse, mutect2, varscan2
- AHR | c.1456T>G p.F486V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV99619820; called by muse, mutect2, varscan2
- AKR7L | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs756582194, COSV101334309; called by muse, mutect2, varscan2
- AKT3 | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99793766; called by muse, mutect2, varscan2
- AL121899.2 | c.1989C>T p.I663= | Splice Region (SNP) | VAF 52/120 reads (43%) | catalogued as rs372838802; called by muse, mutect2, varscan2
- AL592490.1 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV101308151, COSV69424774; called by muse, mutect2, varscan2
- ALAS2 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238284, COSV58193160; called by muse, mutect2, varscan2
- ALB | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs267600248, COSV55736977, COSV55739910; called by muse, mutect2, varscan2
- ALDH1A3 | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV60902555; called by muse, mutect2, varscan2
- ALDH1L1 | c.1290C>A p.F430L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99856997; called by muse, mutect2, varscan2
- ALDH3A1 | c.396G>A p.G132= | Splice Region (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99855944; called by muse, mutect2, varscan2
- ALDOC | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as COSV99257051; called by muse, varscan2
- ALG10B | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 59/121 reads (49%) | catalogued as COSV100439924, COSV58143100; called by muse, mutect2, varscan2
- ALG8 | c.916C>A p.L306I | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV100220140; called by muse, mutect2, varscan2
- ALK | c.3634C>T p.R1212C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1462510005, COSV66589805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV100042763; called by muse, mutect2, varscan2
- ALMS1 | c.3451C>T p.P1151S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV100042765; called by muse, mutect2, varscan2
- ALMS1 | c.5533A>C p.I1845L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100042767; called by muse, mutect2, varscan2
- ALPK1 | c.3720G>T p.E1240D | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99454328; called by muse, mutect2, varscan2
- AMER1 | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as rs763896843, COSV100366346; called by muse, mutect2, varscan2
- AMER1 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.125); catalogued as COSV100366353; called by muse, varscan2
- AMHR2 | c.143A>C p.E48A | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV99143275; called by muse, mutect2, varscan2
- AMOT | c.1613C>T p.S538L (on ENST00000371959 / NM_001113490.1; = p.S129L on NM_133265.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs768294379, COSV59067879; called by muse, mutect2, varscan2
- AMY2A | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs760927676, COSV101340647; called by mutect2, varscan2
- ANGPTL8 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99371022; called by muse, mutect2, varscan2
- ANK2 | c.10187C>A p.S3396Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV100002141, COSV52184715; called by muse, mutect2, varscan2
- ANK3 | c.7543C>A p.L2515I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as rs1266079762, COSV55082059, COSV99781928; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5094G>T p.K1698N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51855942; called by muse, mutect2, varscan2
- ANKRD26 | c.4628C>A p.S1543Y | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.118); catalogued as COSV101063267; called by muse, mutect2, varscan2
- ANKRD30A | c.1768G>T p.E590* (on ENST00000611781; = p.E534* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 54/221 reads (24%) | catalogued as rs1219669225, COSV64605157; called by muse, mutect2, varscan2
- ANKRD30A | c.3298C>A p.L1100I (on ENST00000611781; = p.L1044I on NM_052997.2) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100653710; called by muse, mutect2, varscan2
- ANKRD50 | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72386224; called by muse, mutect2, varscan2
- ANTXR1 | c.572T>G p.I191S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100362660; called by muse, mutect2, varscan2
- ANXA10 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as rs374810057; called by muse, mutect2, varscan2
- ANXA5 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396794753, COSV56640132; called by muse, mutect2, varscan2
- AP2M1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); catalogued as COSV53048043; called by muse, mutect2, varscan2
- AP4E1 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs144189610, COSV55915364; ClinVar: uncertain significance; called by muse, varscan2
- AP4E1 | c.2540C>A p.S847Y | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99956753; called by muse, varscan2
- APC | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs587779805, COSV57325373, COSV57365922, COSV99965333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.4630G>T p.E1544* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV57327947, COSV57331833, COSV57342321, COSV57357142; called by mutect2, varscan2
- APLP1 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758414613, COSV55707101; called by muse, mutect2, varscan2
- APLP1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs778308918, COSV55702037; called by muse, mutect2, varscan2
- APOBEC3F | c.604T>A p.F202I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.867); catalogued as rs780286886, COSV100415217; called by muse, mutect2, varscan2
- ARHGAP17 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs775863425, COSV51507886; called by muse, mutect2, varscan2
- ARHGAP17 | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV99253591; called by muse, mutect2, varscan2
- ARHGEF2 | c.1775G>A p.R592Q (on ENST00000361247 / NM_001162383.2; = p.R564Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV100560692; called by muse, mutect2, varscan2
- ARHGEF28 | c.1263A>C p.E421D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs770267470, COSV99709314; called by muse, mutect2, varscan2
- ARHGEF7 | c.1643T>C p.I548T (on ENST00000375741 / NM_001113511.2; = p.I370T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99521693; called by muse, mutect2, varscan2
- ARID2 | c.3308del p.S1103Ifs*53 | Frame Shift Del (DEL) | VAF 37/88 reads (42%) | catalogued as COSV57595546; called by mutect2, pindel, varscan2
- ARID3B | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as rs550927259, COSV60557518; called by muse, mutect2, varscan2
- ARID5B | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV99689852; called by muse, mutect2, varscan2
- ARPP21 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99492283; called by muse, mutect2, varscan2
- ART3 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV100587809; called by muse, mutect2, varscan2
- ASB3 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs759668373, COSV55074659; called by muse, mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASIC5 | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as rs777476458, COSV101611147; called by muse, mutect2, varscan2
- ASNS | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1399973379, COSV99446363, COSV99446930; called by muse, mutect2, varscan2
- ASPH | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101063965, COSV65245687; called by muse, mutect2, varscan2
- ASPH | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV100727611; called by muse, mutect2, varscan2
- ASPM | c.530A>C p.K177T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99660569; called by muse, mutect2, varscan2
- ASZ1 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1466789937, COSV99498082; called by muse, mutect2, varscan2
- ATG2B | c.5376G>T p.K1792N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99952093; called by muse, mutect2, varscan2
- ATG2B | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV63426033; called by muse, mutect2, varscan2
- ATG4A | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1296309836, COSV100619755, COSV58964548; called by muse, mutect2, varscan2
- ATG4C | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146646910; called by muse, mutect2, varscan2
- ATM | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769166447, CM1314652, COSV53734045, COSV53758870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.6848C>A p.S2283* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV53762880, COSV99590091; called by muse, mutect2, varscan2
- ATP10D | c.1882C>A p.L628I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV56703283, COSV99905728; called by muse, mutect2, varscan2
- ATP2A2 | c.119-1G>A p.X40_splice | Splice Site (SNP) | VAF 34/85 reads (40%) | catalogued as COSV100428694; called by muse, mutect2, varscan2
- ATP2A3 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV99989314; called by muse, mutect2, varscan2
- ATP4A | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52866740; called by muse, mutect2, varscan2
- ATP8B4 | c.3571A>C p.K1191Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs753163809, COSV99466012; called by muse, mutect2, varscan2
- ATP8B4 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as COSV52717337, COSV52719277; called by muse, mutect2, varscan2
- ATRNL1 | c.2416-1G>A p.X806_splice | Splice Site (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100371113, COSV58100596; called by muse, mutect2, varscan2
- ATRX | c.3155A>C p.K1052T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as COSV64883423; called by muse, mutect2, varscan2
- AVEN | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as rs766300982, COSV60734025; called by muse, mutect2, varscan2
- B3GAT2 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100017095; called by muse, mutect2, varscan2
- B4GALNT1 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100247186; called by muse, mutect2, varscan2
- BANK1 | c.2353C>A p.H785N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as COSV100536462; called by muse, mutect2, varscan2
- BAZ2B | c.5297C>T p.A1766V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.699); catalogued as COSV100600731; called by muse, mutect2, varscan2
- BCHE | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV100012674; called by muse, mutect2, varscan2
- BCHE | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100012676; called by muse, mutect2, varscan2
- BCLAF1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as rs1487882129, COSV50361469; called by muse, mutect2, varscan2
- BEX1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 35/79 reads (44%) | catalogued as COSV101022493; called by muse, mutect2, varscan2
- BICD1 | c.2680C>A p.L894I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); catalogued as COSV99862572; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4875G>T p.K1625N | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated, low confidence (0.98); catalogued as COSV100863800; called by muse, mutect2, varscan2
- BMP3 | c.378C>A p.N126K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.519); catalogued as COSV99261765; called by muse, mutect2, varscan2
- BMP3 | c.1347C>A p.F449L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51082268; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 40/77 reads (52%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BMX | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100564501; called by muse, mutect2, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BPIFB3 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100972364; called by muse, mutect2, varscan2
- BRCA2 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as COSV101204330; called by muse, mutect2, varscan2
- BRCA2 | c.2098T>A p.L700I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs431825293, COSV101204331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.7491G>T p.K2497N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV101204332; called by muse, mutect2, varscan2
- BRWD3 | c.3264C>A p.H1088Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as COSV100956188; called by muse, mutect2, varscan2
- BRWD3 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as rs1419641872, COSV64743829; called by muse, mutect2, varscan2
- BSN | c.8283G>T p.K2761N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99608772; called by muse, mutect2, varscan2
- BTK | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100437655; called by muse, mutect2, varscan2
- BUD23 | c.688T>C p.F230L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.41); catalogued as COSV99736681; called by muse, mutect2, varscan2
- C14orf39 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1219258922, COSV58781162; called by muse, mutect2, varscan2
- C2CD3 | c.5313C>A p.F1771L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100486892; called by muse, mutect2, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2orf16 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368267439; called by mutect2, varscan2
- C6 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs544678725, COSV54708806; called by muse, mutect2, varscan2
- C8orf76 | c.473C>A p.S158Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99415086; called by muse, mutect2, varscan2
- CA1 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99809983; called by muse, mutect2, varscan2
- CA13 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58797264, COSV58798520; called by muse, mutect2, varscan2
- CA5A | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200681449, COSV59238863; called by muse, mutect2, varscan2
- CABCOCO1 | c.33T>G p.F11L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100357931; called by muse, mutect2, varscan2
- CACNA1C | c.2888C>A p.S963Y | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59707867, COSV59721607; called by muse, mutect2, varscan2
- CACNA1D | c.3807G>T p.W1269C (on ENST00000350061 / NM_001128840.3; = p.W1289C on NM_000720.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99858548; called by muse, mutect2, varscan2
- CACNA1F | c.2758C>A p.L920I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.349); catalogued as COSV59903587; called by muse, mutect2, varscan2
- CACNG6 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99403482; called by muse, mutect2, varscan2
- CAMLG | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765331970, COSV51804427; called by muse, mutect2, varscan2
- CARD14 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs984278499, COSV100712576; called by muse, mutect2, varscan2
- CARD17 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.34); catalogued as rs755551973, COSV100995238; called by muse, mutect2, varscan2
- CARNS1 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs780920363, COSV100322057; called by muse, mutect2, varscan2
- CASC3 | c.1607_1608insA p.P537Sfs*13 | Frame Shift Ins (INS) | VAF 31/85 reads (36%) | catalogued as COSV99229795; called by mutect2, pindel, varscan2
- CASK | c.840T>G p.D280E | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV100587342; called by muse, mutect2, varscan2
- CASKIN2 | c.3126C>A p.S1042R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as COSV100050559; called by muse, mutect2, varscan2
- CASP5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747113465, COSV52828282; called by muse, mutect2, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, mutect2, varscan2
- CASS4 | c.1659G>T p.Q553H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100824748; called by muse, mutect2, varscan2
- CATSPERB | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56424494, COSV99831391; called by muse, mutect2, varscan2
- CAVIN4 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs191289133, COSV56867210; called by muse, mutect2, varscan2
- CBFA2T2 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as COSV100674051; called by muse, mutect2, varscan2
- CCDC102B | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100103802, COSV100104969; called by muse, mutect2, varscan2
- CCDC110 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100293735; called by muse, mutect2
- CCDC110 | c.1461G>T p.K487N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV100294000; called by muse, mutect2, varscan2
- CCDC126 | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100278016; called by muse, mutect2, varscan2
- CCDC138 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99719239; called by muse, mutect2, varscan2
- CCDC178 | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV100285197; called by muse, mutect2, varscan2
- CCDC18 | c.3851T>G p.I1284S (on ENST00000343253 / NM_001306076.1; = p.I1285S on NM_206886.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100159691; called by muse, mutect2, varscan2
- CCDC30 | c.588T>G p.I196M (on ENST00000340612; = p.I153M on NM_001080850.3) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.561); catalogued as COSV100501405; called by mutect2, varscan2
- CCDC50 | c.362T>C p.L121S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101165307; called by muse, mutect2, varscan2
- CCDC63 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs141094849, COSV57529948; called by muse, mutect2, varscan2
- CCDC88A | c.4148T>G p.F1383C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99710624; called by muse, mutect2, varscan2
- CCDC92 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753848940, COSV99435627; called by muse, mutect2, varscan2
- CCN3 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV52383765; called by muse, mutect2, varscan2
- CCNB3 | c.3144C>A p.F1048L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV52074040, COSV99329245; called by muse, mutect2, varscan2
- CCNT1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV56065445; called by muse, mutect2, varscan2
- CD163L1 | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769098820, COSV58019485; called by muse, mutect2, varscan2
- CD19 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV61188084; called by muse, mutect2, varscan2
- CD55 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as CM076088, COSV58576670; called by muse, mutect2
- CD72 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.448); catalogued as COSV99427504; called by muse, mutect2, varscan2
- CD83 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100997800; called by muse, mutect2, varscan2
- CDC14B | c.671T>G p.F224C | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99685807; called by muse, mutect2, varscan2
- CDH1 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs864622198, COSV55731076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH11 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV51780475, COSV99218755; called by muse, mutect2, varscan2
- CDH23 | c.8165T>C p.F2722S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99821615; called by muse, mutect2, varscan2
- CDH26 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.602); catalogued as COSV99722608; called by muse, mutect2, varscan2
- CDH7 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100542578; called by muse, mutect2, varscan2
- CDH7 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100542579; called by muse, mutect2, varscan2
- CDK17 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.216); catalogued as rs1280012538, COSV99702807; called by muse, mutect2, varscan2
- CDS1 | c.252A>C p.K84N | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV99880786; called by muse, mutect2, varscan2
- CDV3 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.757); catalogued as COSV99394312; called by muse, mutect2, varscan2
- CELA3A | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs202213007, COSV99266577; called by muse, varscan2
- CELA3A | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs369076077; called by muse, varscan2
- CENPC | c.1491G>T p.K497N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99894055; called by muse, mutect2, varscan2
- CENPE | c.2429C>T p.S810L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779464384, COSV54377053; called by muse, mutect2, varscan2
- CENPV | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.464); catalogued as rs778078087, COSV55333443; called by muse, mutect2, varscan2
- CEP120 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100071179; called by muse, mutect2, varscan2
- CEP170 | c.3577C>T p.P1193S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV100317272, COSV60513928; called by muse, mutect2
- CEP290 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs753374614, COSV58353842, COSV58355012; called by muse, mutect2, varscan2
- CEP63 | c.1500G>T p.E500D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV59675250; called by muse, mutect2, varscan2
- CEPT1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs773409190, COSV100853487; called by muse, mutect2, varscan2
- CERS6 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 5/70 reads (7%) | catalogued as COSV99987175, COSV99987746; called by muse, mutect2
- CFAP100 | c.692A>C p.E231A | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100729280; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.738); catalogued as rs760491203, COSV100291914; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CFAP47 | c.4585G>A p.A1529T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100545448; called by muse, mutect2, varscan2
- CFAP54 | c.8261C>T p.S2754L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs568368996, COSV61572344; called by muse, mutect2, varscan2
- CFAP65 | c.4720-1G>T p.X1574_splice | Splice Site (SNP) | VAF 6/69 reads (9%) | catalogued as COSV100445446; called by muse, mutect2
- CFHR4 | c.1072G>T p.E358* (on ENST00000367416 / NM_001201551.2; = p.E112* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as rs1309004238, COSV52223978, COSV99260691; called by muse, mutect2, varscan2
- CHD2 | c.5392G>A p.D1798N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.627); catalogued as rs1057518463, COSV101245427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHL1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as rs754718767, COSV56598549; called by muse, mutect2, varscan2
- CHRNA9 | c.1374C>A p.F458L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.856); catalogued as COSV100038990, COSV59574846; called by mutect2, varscan2
- CIRBP | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.043); catalogued as COSV100309810; called by muse, mutect2
- CIT | c.1668G>A p.E556= | Splice Region (SNP) | VAF 18/26 reads (69%) | catalogued as COSV99949990; called by muse, mutect2, varscan2
- CLASP1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as rs1189932217, COSV55313347; called by muse, mutect2, varscan2
- CLASP2 | c.3473T>G p.I1158S (on ENST00000359576; = p.I1157S on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100223621; called by muse, mutect2, varscan2
- CLCA4 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV55367070; called by muse, mutect2, varscan2
- CLCN5 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100259743; called by muse, mutect2, varscan2
- CLCN5 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs782574529, COSV100260220, COSV100260230; called by muse, mutect2, varscan2
- CLDN16 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1444245867, CM085326, COSV53228283; called by muse, mutect2, varscan2
- CLEC12B | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100138939, COSV100139109; called by muse, mutect2, varscan2
- CLEC3A | c.518G>A p.R173Q (on ENST00000651443; = p.R164Q on NM_005752.6) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs753496661, COSV100222264; called by muse, mutect2, varscan2
- CLGN | c.660C>A p.F220L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as COSV57773385, COSV57776268; called by muse, mutect2, varscan2
- CLIC2 | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58935656; called by muse, mutect2, varscan2
- CLK4 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV100309011; called by muse, mutect2, varscan2
- CMYA5 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101484087, COSV101484137; called by muse, mutect2
- CNDP2 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV100159151, COSV60839668; called by muse, mutect2, varscan2
- CNGB1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.695); catalogued as rs772006490, COSV51898009; called by muse, mutect2, varscan2
- CNOT1 | c.4949G>A p.R1650Q | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55317545; called by muse, mutect2, varscan2
- CNTN5 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs200579368, COSV54326826; called by muse, mutect2, varscan2
- CNTNAP1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV52853506, COSV99226242; called by muse, mutect2
- CNTNAP1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.138); catalogued as rs868749538, COSV52847713; called by muse, mutect2, varscan2
- CNTNAP4 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs570306162, COSV56667755; called by muse, mutect2, varscan2
- COG2 | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs973011008, COSV64186171; called by muse, mutect2, varscan2
- COL11A1 | c.4960A>C p.K1654Q | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100617018; called by muse, mutect2, varscan2
- COL20A1 | c.3232G>T p.G1078* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100490734; called by muse, mutect2, varscan2
- COL28A1 | c.617C>A p.S206* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV101258698, COSV99063629; called by muse, mutect2, varscan2
- COL4A6 | c.2636G>T p.G879V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564316, COSV57877985; called by muse, mutect2, varscan2
- COL5A3 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319056; called by muse, mutect2
- COL6A1 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100720267, COSV62612669; called by muse, mutect2, varscan2
- COL6A3 | c.8478T>G p.F2826L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs748250269, COSV55114156, COSV99799007; called by muse, mutect2, varscan2
- COL6A3 | c.7037C>T p.S2346L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs377168716, COSV99799009; called by muse, mutect2, varscan2
- COL6A5 | c.6644C>A p.S2215Y (on ENST00000312481; = p.S2211Y on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV55206226; called by muse, mutect2, varscan2
- COLQ | c.59T>A p.I20N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.121); catalogued as COSV101083023; called by muse, mutect2, varscan2
- COMMD10 | c.371T>G p.F124C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99174553; called by muse, mutect2, varscan2
- CORO1C | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV99776017; called by muse, mutect2, varscan2
- CPNE3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs376221396; called by muse, mutect2, varscan2
- CPNE4 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101456739; called by muse, mutect2, varscan2
- CPNE8 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100504553; called by muse, mutect2
- CRB1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs563857130, COSV66328727, COSV66328731; called by muse, mutect2, varscan2
- CREBBP | c.6011G>A p.R2004Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as rs1279369054, COSV99270488; called by muse, mutect2
- CRPPA | c.1207G>T p.E403* (on ENST00000407010 / NM_001368197.1; = p.E353* on NM_001101417.4) | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV67908600, COSV67909485; called by mutect2, varscan2
- CRYBA4 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as rs200572268; called by muse, mutect2, varscan2
- CSMD2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV99591402; called by muse, mutect2, varscan2
- CSMD2 | c.285G>A p.R95= | Splice Region (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99591405; called by muse, mutect2, varscan2
- CSMD3 | c.7792C>T p.R2598* (on ENST00000297405 / NM_001363185.1; = p.R2494* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV52119954; called by muse, mutect2, varscan2
- CSMD3 | c.2814A>G p.E938= (on ENST00000297405 / NM_001363185.1; = p.E834= on NM_052900.3) | Splice Region (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99837002; called by muse, mutect2, varscan2
- CSMD3 | c.2118G>T p.E706D (on ENST00000297405 / NM_001363185.1; = p.E602D on NM_052900.3) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV99837004; called by muse, mutect2, varscan2
- CTRB1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs563820594, COSV99366818; called by muse, mutect2, varscan2
- CUL3 | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 44/87 reads (51%) | catalogued as COSV100024340, COSV52370374; called by muse, mutect2, varscan2
- CUL4B | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as CM070068, COSV60684870; called by muse, mutect2, varscan2
- CUL4B | c.1308C>A p.T436= | Splice Region (SNP) | VAF 19/53 reads (36%) | catalogued as COSV60685341; called by muse, mutect2, varscan2
- CYB5R1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs762768895, COSV65916931; called by muse, mutect2, varscan2
- CYP17A1 | c.1251C>A p.F417L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100882115; called by muse, mutect2, varscan2
- CYP19A1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV99547781; called by muse, mutect2
- CYP24A1 | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.302); catalogued as COSV99398373; called by muse, mutect2
- CYP2A6 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV99991908; called by muse, mutect2, varscan2
- CYP2A7 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as rs200261904, COSV99394172; called by muse, mutect2, varscan2
- CYP2C19 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100990544, COSV64908195; called by muse, mutect2
- CYP2R1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as rs576642411, COSV58126807; called by muse, mutect2, varscan2
- CYP3A4 | c.375A>C p.E125D | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100315694; called by muse, mutect2, varscan2
- CYP46A1 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99952677; called by muse, mutect2, varscan2
- CYP4F12 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV100215898; called by muse, mutect2, varscan2
- DAAM1 | c.2859T>G p.F953L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV100658479; called by muse, mutect2, varscan2
- DACH2 | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.272); catalogued as COSV100913393; called by muse, mutect2, varscan2
- DBP | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs950476082, COSV99320520; called by muse, mutect2, varscan2
- DCAF4L1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1224359974, COSV60787139; called by muse, mutect2, varscan2
- DCT | c.1226G>T p.R409I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65468316; called by muse, mutect2, varscan2
- DCUN1D1 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99489929; called by muse, mutect2, varscan2
- DCUN1D3 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60953177; called by muse, mutect2
- DDHD1 | c.592G>A p.E198K (on ENST00000323669; = p.E395K on NM_030637.3) | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV100079649; called by mutect2, varscan2
- DDX17 | c.14T>G p.F5C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | PolyPhen benign (0); catalogued as COSV99318815; called by muse, mutect2, varscan2
- DDX4 | c.1708A>C p.I570L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100737582; called by muse, mutect2, varscan2
- DENND4A | c.1841A>C p.K614T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101475365; called by muse, mutect2, varscan2
- DENND4C | c.1874T>G p.F625C | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100991390; called by muse, mutect2, varscan2
- DEPDC4 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100147364; called by muse, mutect2, varscan2
- DEPDC4 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV54552923; called by muse, mutect2, varscan2
- DGAT1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139792712; called by muse, mutect2, varscan2
- DGKH | c.3055G>T p.E1019* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99818987; called by muse, mutect2
- DGKK | c.2427T>G p.D809E | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.251); catalogued as COSV101053061; called by muse, mutect2, varscan2
- DGKK | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101053062; called by muse, mutect2, varscan2
- DHX9 | c.3148C>T p.R1050* | Nonsense Mutation (SNP) | VAF 39/85 reads (46%) | catalogued as rs1438628800, COSV62358169; called by muse, mutect2, varscan2
- DIAPH3 | c.2482G>A p.E828K (on ENST00000400324 / NM_001042517.2; = p.E565K on NM_030932.3) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs765318944, COSV57368501; called by muse, mutect2, varscan2
- DIAPH3 | c.1861G>A p.G621R (on ENST00000400324 / NM_001042517.2; = p.G358R on NM_030932.3) | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs750299647, COSV99933763; called by muse, mutect2, varscan2
- DIAPH3 | c.1060G>T p.D354Y (on ENST00000400324 / NM_001042517.2; = p.D91Y on NM_030932.3) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99933765; called by muse, mutect2, varscan2
- DLG2 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751367052, COSV54622005; called by muse, mutect2, varscan2
- DLX6 | c.444A>C p.Q148H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99142387; called by muse, mutect2, varscan2
- DMD | c.10554G>A p.R3518= | Splice Region (SNP) | VAF 33/115 reads (29%) | catalogued as COSV100627742; called by muse, mutect2, varscan2
- DMD | c.10336G>T p.E3446* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100627746; called by muse, mutect2, varscan2
- DMD | c.6379C>A p.L2127I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.275); catalogued as COSV63741699, COSV63803104; called by muse, mutect2, varscan2
- DMD | c.6166C>A p.H2056N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100820278; called by muse, mutect2, varscan2
- DMD | c.330G>T p.L110F | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55859820; called by muse, mutect2
- DNAAF2 | c.1814A>G p.H605R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs756451865, COSV100024140; called by muse, mutect2, varscan2
- DNAH10 | c.3628G>T p.E1210* (on ENST00000409039; = p.E1149* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV101292335; called by muse, mutect2, varscan2
- DNAH11 | c.5896C>A p.H1966N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV100179519, COSV60955828; called by muse, mutect2, varscan2
- DNAJC1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs781040896, COSV65412840; called by muse, mutect2, varscan2
- DNAJC13 | c.5053G>T p.E1685* | Nonsense Mutation (SNP) | VAF 48/102 reads (47%) | catalogued as COSV99607461, COSV99608100; called by muse, mutect2, varscan2
- DNAJC24 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as COSV71938535; called by muse, mutect2, varscan2
- DNAJC25 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745598077, COSV57956287; called by muse, mutect2, varscan2
- DNAJC5B | c.120-1G>T p.X40_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52535673; called by muse, mutect2
- DNM3 | c.1028G>T p.R343I | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.294); catalogued as COSV62455664; called by muse, mutect2, varscan2
- DNM3 | c.1735C>T p.R579W (on ENST00000355305 / NM_001350206.2; = p.R569W on NM_015569.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253104482, COSV62456982; called by muse, mutect2
- DNMBP | c.1993C>T p.R665* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs867943525, COSV60628161; called by muse, mutect2, varscan2
- DOCK11 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV99354069; called by muse, mutect2, varscan2
- DOCK2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99913128; called by muse, mutect2, varscan2
- DOCK2 | c.5030G>T p.R1677I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99913133; called by muse, mutect2, varscan2
- DOCK8 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV101209957; called by muse, mutect2, varscan2
- DPEP2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs760294074, COSV52055330; called by muse, mutect2, varscan2
- DPPA4 | c.431C>A p.S144* | Nonsense Mutation (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100169492, COSV59511624, COSV59512548; called by muse, mutect2
- DRC1 | c.2108C>A p.S703Y | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.59); catalogued as COSV99717955; called by muse, mutect2, varscan2
- DRP2 | c.1284A>C p.E428D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV65809979; called by muse, mutect2, varscan2
- DSCAML1 | c.472G>A p.D158N (on ENST00000321322; = p.D98N on NM_020693.4) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs1276241297, COSV58396974; called by muse, mutect2, varscan2
- DSG3 | c.2337C>A p.Y779* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | catalogued as COSV99934318; called by muse, mutect2, varscan2
- DSG4 | c.1649T>G p.I550S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV100355992; called by muse, mutect2, varscan2
- DSG4 | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143509440; called by muse, mutect2, varscan2
- DST | c.8569G>T p.E2857* | Nonsense Mutation (SNP) | VAF 28/41 reads (68%) | catalogued as rs747173454, COSV99757328; called by muse, mutect2, varscan2
- DTX4 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs1386126542, COSV99915545; called by muse, mutect2, varscan2
- DTX4 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99915548; called by muse, mutect2, varscan2
- DUSP11 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV55593618; called by muse, mutect2, varscan2
- DUSP8 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs1384722044, COSV59030101; called by muse, mutect2, varscan2
- DYRK1A | c.971G>A p.S324N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100117982; called by muse, mutect2, varscan2
- DYSF | c.5860G>A p.E1954K | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.84); PolyPhen benign (0.248); catalogued as rs1356633122, COSV99247888; called by muse, mutect2, varscan2
- DZIP3 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs767859352, COSV100847856; called by muse, mutect2, varscan2
- EBF3 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV62475179; called by muse, mutect2, varscan2
- ECM2 | c.394C>A p.L132I | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.114); catalogued as COSV60738986; called by muse, mutect2, varscan2
- ECPAS | c.3105A>C p.E1035D | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99398515; called by muse, mutect2, varscan2
- ECT2 | c.959A>C p.D320A (on ENST00000392692 / NM_001349098.2; = p.D289A on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99221451; called by muse, mutect2
- ECT2 | c.1069G>T p.A357S (on ENST00000392692 / NM_001349098.2; = p.A326S on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99221453; called by muse, mutect2, varscan2
- EFHB | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55553238; called by muse, mutect2, varscan2
- EFHC2 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as rs1317786565, COSV100637961; called by muse, mutect2, varscan2
- EFR3A | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs143933422, COSV54453100; called by muse, mutect2, varscan2
- EFTUD2 | c.300G>T p.K100N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1396743107, COSV68182791; called by muse, mutect2, varscan2
- EGFL6 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs969155152, COSV63635308; called by muse, mutect2, varscan2
- EIF2B4 | c.1031G>A p.R344Q (on ENST00000347454 / NM_001034116.2; = p.R343Q on NM_015636.3) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs141025043; called by muse, mutect2, varscan2
- EIF3A | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as rs778928763, COSV100974651; called by muse, mutect2, varscan2
- EIF4G2 | c.994A>C p.K332Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV101150917; called by muse, mutect2, varscan2
- EIF4G2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100379339, COSV60598890; called by muse, mutect2, varscan2
- ELAVL3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs769092105, COSV100820796; called by muse, mutect2, varscan2
- ELOA2 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV55293008; called by muse, mutect2
- EMILIN2 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54421311, COSV99598607; called by muse, mutect2, varscan2
- EML4 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV59300120; called by muse, mutect2, varscan2
- EMX2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV101463615; called by muse, mutect2, varscan2
- ENDOG | c.611+1G>A p.X204_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as rs760067135, COSV100778225; called by muse, mutect2, varscan2
- ENOX2 | c.1351G>T p.E451* (on ENST00000338144 / NM_001382520.1; = p.E422* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100584256, COSV57650935; called by muse, mutect2, varscan2
- ENPP3 | c.2219G>T p.R740I | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100717478; called by muse, mutect2, varscan2
- ENTHD1 | c.317T>G p.F106C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100288841; called by muse, mutect2, varscan2
- EPB41 | c.1458T>G p.F486L (on ENST00000343067 / NM_001166005.2; = p.F277L on NM_004437.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100548830; called by muse, mutect2, varscan2
- EPB41L3 | c.930A>C p.E310D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100549486; called by muse, mutect2, varscan2
- EPHA3 | c.2405C>A p.T802K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100345989; called by muse, mutect2, varscan2
- EPHA8 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99385047; called by muse, mutect2, varscan2
- EPRS1 | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598382, COSV100859406; called by muse, mutect2, varscan2
- ERBIN | c.2377A>C p.T793P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as COSV99397078; called by muse, mutect2, varscan2
- ERICH3 | c.475A>C p.N159H | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV100444692; called by muse, mutect2, varscan2
- ERICH6 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.811); catalogued as rs267599648, COSV99901743; called by muse, mutect2, varscan2
- ERLIN1 | c.336T>G p.D112E | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.291); catalogued as COSV100962261; called by muse, mutect2, varscan2
- ERP27 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV56762868; called by mutect2, varscan2
- EXOC6B | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as rs1251698068, COSV55549902; called by muse, mutect2, varscan2
- F13B | c.92A>C p.E31A | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100803329; called by muse, mutect2, varscan2
- F5 | c.3475T>C p.Y1159H | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs148238652, CD051305; called by muse, mutect2, varscan2
- FABP1 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV55558177, COSV99860909; called by muse, mutect2, varscan2
- FABP9 | c.380G>T p.R127I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100986938, COSV66911794; called by muse, varscan2
- FAM111B | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs750701880, COSV59111805, COSV59111963; called by muse, mutect2, varscan2
- FAM114A2 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100697727; called by muse, mutect2, varscan2
- FAM13B | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV99221483; called by muse, mutect2, varscan2
- FAM184A | c.2734C>A p.L912I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100137943; called by muse, mutect2, varscan2
- FAM204A | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100977372; called by muse, mutect2, varscan2
- FAM204A | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 42/94 reads (45%) | catalogued as COSV100977373; called by muse, mutect2, varscan2
- FAM83B | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.438); catalogued as COSV100174582; called by muse, mutect2, varscan2
- FAM90A1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.655); catalogued as rs750289614, COSV56715116; called by muse, varscan2
- FASTKD1 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs371530621; called by muse, mutect2
- FAT1 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1321370436, COSV71675810; called by muse, mutect2, varscan2
- FAT2 | c.1865A>G p.K622R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99943248; called by muse, mutect2, varscan2
- FAT4 | c.10159G>A p.D3387N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100628968; called by muse, mutect2, varscan2
- FBN3 | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs774181301, COSV54474493, COSV99561137; called by muse, mutect2
- FBXL13 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100501733; called by muse, mutect2, varscan2
- FBXL3 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV62918573; called by muse, mutect2, varscan2
- FBXL5 | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100377921; called by muse, mutect2, varscan2
- FBXO39 | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV100386218; called by muse, mutect2, varscan2
- FBXO43 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV101413869; called by muse, mutect2, varscan2
- FCGR2A | c.745A>C p.N249H (on ENST00000271450 / NM_001136219.3; = p.N248H on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.36); catalogued as COSV99615440; called by muse, mutect2, varscan2
- FCGR3A | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV100914671; called by muse, mutect2
- FCHSD2 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV100238587; called by muse, mutect2, varscan2
- FGF14 | c.632T>G p.L211W | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101086563; called by muse, mutect2, varscan2
- FGF5 | c.738G>T p.K246N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.245); catalogued as COSV100427919; called by muse, mutect2, varscan2
- FHDC1 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV52599437; called by muse, mutect2, varscan2
- FHL5 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100459504, COSV58741355; called by muse, mutect2, varscan2
- FLG2 | c.5290C>A p.H1764N | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV101165943, COSV66168894, COSV99063668; called by muse, mutect2
- FLG2 | c.2594C>T p.S865L | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as rs371756979; called by muse, mutect2, varscan2
- FLRT2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1362116180, COSV100420545; called by muse, mutect2, varscan2
- FLRT3 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | catalogued as rs1031673015, COSV99434923; called by muse, mutect2, varscan2
- FLT4 | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99987401; called by muse, mutect2, varscan2
- FLVCR2 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV53161594, COSV53163145; called by muse, mutect2, varscan2
- FMNL3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs181518753, COSV53299136; called by muse, varscan2
- FN1 | c.4145G>T p.R1382L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV100117332, COSV60553117; called by muse, mutect2, varscan2
- FNBP4 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 28/39 reads (72%) | catalogued as COSV55447247; called by muse, mutect2, varscan2
- FOLH1 | c.1814G>T p.R605I | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV57050899, COSV99923355; called by muse, mutect2, varscan2
- FOXA2 | c.497C>T p.S166L (on ENST00000377115 / NM_153675.3; = p.S172L on NM_021784.5) | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65796636; called by muse, mutect2
- FOXF1 | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52288020, COSV99296548; called by muse, mutect2, varscan2
- FOXI1 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs1487920356, COSV100089441; called by muse, mutect2, varscan2
- FOXO3 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100669932; called by muse, mutect2
- FOXP2 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs576347421, COSV100646847; called by muse, mutect2, varscan2
- FOXS1 | c.672C>A p.F224L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.275); catalogued as COSV54067428, COSV99639739; called by muse, mutect2, varscan2
- FRA10AC1 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | catalogued as COSV100784716; called by muse, mutect2, varscan2
- FRAS1 | c.7546C>T p.R2516C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs374802955; called by muse, mutect2, varscan2
- FREM2 | c.3131G>A p.R1044K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV54828291, COSV99749187; called by muse, mutect2, varscan2
- FREM2 | c.8589G>T p.M2863I | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV54840449, COSV99749189; called by muse, mutect2, varscan2
- FRRS1L | c.444C>A p.F148L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV73746357; called by muse, mutect2, varscan2
- FSHB | c.22T>G p.F8V | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54223056, COSV99569448; called by muse, mutect2, varscan2
- FSIP2 | c.16228C>A p.L5410I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as COSV100555422; called by muse, mutect2, varscan2
- FSIP2 | c.18664G>T p.E6222* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs775082765, COSV100554465; called by muse, varscan2
- FSIP2 | c.18692T>G p.L6231R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100555424; called by muse, varscan2
- FYCO1 | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as rs1559466202, COSV99945804; called by muse, mutect2, varscan2
- GABRA2 | c.307A>C p.K103Q | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as COSV62912400; called by muse, mutect2, varscan2
- GABRA3 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100942896; called by muse, mutect2, varscan2
- GABRA4 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51931436, COSV99974180; called by muse, mutect2, varscan2
- GABRR1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV101033955, COSV65619030; called by muse, mutect2, varscan2
- GALNT1 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV52451451; called by muse, mutect2, varscan2
- GAPVD1 | c.225A>C p.K75N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.966); catalogued as rs111441962, COSV99783338; called by muse, mutect2, varscan2
- GAPVD1 | c.1425G>T p.K475N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as rs779417104, COSV99782427; called by muse, varscan2
- GAS7 | c.494G>A p.S165N (on ENST00000432992 / NM_201433.2; = p.S25N on NM_003644.3) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs748250184, COSV100095868; called by muse, mutect2, varscan2
- GBA2 | c.1968G>T p.M656I | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100803414; called by muse, mutect2, varscan2
- GBE1 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752100789, COSV70099062; called by muse, mutect2, varscan2
- GBP1 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 103/202 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100976273; called by muse, mutect2, varscan2
- GBP2 | c.1460T>C p.I487T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs1249896301, COSV100975404; called by muse, mutect2, varscan2
- GCA | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs563127943, COSV52026884; called by muse, mutect2, varscan2
- GCC2 | c.4884C>A p.F1628L | Missense Mutation (SNP) | VAF 181/757 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100565498; called by muse, mutect2, varscan2
- GDPD2 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.757); catalogued as rs755982284, COSV100978646; called by muse, mutect2, varscan2
- GEMIN5 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1217968555, COSV53560334; called by muse, mutect2, varscan2
- GFPT1 | c.1630G>A p.E544K (on ENST00000357308 / NM_001244710.2; = p.E526K on NM_002056.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs755583835, COSV100622862; called by muse, mutect2, varscan2
- GHSR | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1250898120, COSV53837368; called by muse, mutect2, varscan2
- GLG1 | c.3026G>T p.C1009F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215889; called by muse, mutect2, varscan2
- GLG1 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV99215891; called by muse, mutect2
- GLRA1 | c.1280C>T p.S427F (on ENST00000455880 / NM_001146040.2; = p.S419F on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199581; called by muse, mutect2
- GLT1D1 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV99896814; called by muse, mutect2, varscan2
- GNAS | c.328A>G p.S110G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); catalogued as COSV100006782; called by muse, mutect2, varscan2
- GOLGB1 | c.8747C>T p.P2916L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); catalogued as COSV100511073; called by muse, mutect2, varscan2
- GOLGB1 | c.5122G>A p.D1708N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs759392269, COSV100511076; called by muse, mutect2, varscan2
- GON4L | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV99674649; called by muse, mutect2, varscan2
- GPAT3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs143173203; called by muse, mutect2, varscan2
- GPHA2 | c.210C>A p.Y70* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99376209; called by muse, mutect2, varscan2
- GPR135 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.355); catalogued as rs375777007, COSV101229326; called by muse, mutect2, varscan2
- GPR158 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs776684937; called by muse, varscan2
- GPR75 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs778576313, COSV61827024; called by muse, mutect2, varscan2
- GPR87 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.235); catalogued as rs764492925, COSV53463046; called by muse, mutect2, varscan2
- GRB10 | c.781T>G p.F261V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60013187; called by muse, mutect2, varscan2
- GRIA2 | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV52386606; called by muse, mutect2, varscan2
- GRIA2 | c.2579C>T p.S860L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.203); catalogued as rs756724003, COSV99643486, COSV99644760; called by muse, mutect2, varscan2
- GRIPAP1 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100904313; called by muse, mutect2, varscan2
- GRM1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1196671438, COSV51159383, COSV51197406; called by muse, mutect2, varscan2
- GRM3 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs967635794, COSV64468638; called by muse, mutect2, varscan2
- GRXCR1 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs776474443, COSV101295701, COSV67672367; called by muse, mutect2, varscan2
- GUCY1B1 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100025629; called by muse, mutect2, varscan2
- GUF1 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs769392101, COSV55784905; called by muse, mutect2, varscan2
- H3-5 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV61187197; called by muse, mutect2, varscan2
- HCN1 | c.1475G>T p.R492I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV57504166, COSV57539881; called by muse, mutect2, varscan2
- HCN1 | c.1227G>T p.E409D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100300711; called by muse, mutect2, varscan2
- HEATR1 | c.804T>G p.I268M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100857671; called by muse, mutect2, varscan2
- HECW1 | c.4012C>A p.L1338I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.882); catalogued as COSV101223840; called by muse, mutect2, varscan2
- HECW2 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.616); catalogued as rs1188606678, COSV53671813; called by muse, mutect2, varscan2
- HEMGN | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs1451210817, COSV52326091; called by muse, mutect2, varscan2
- HERC2 | c.11540T>G p.F3847C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99874537; called by muse, mutect2, varscan2
- HERC6 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1433352072, COSV99986735; called by muse, mutect2, varscan2
- HERPUD2 | c.226C>A p.Q76K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV100257999; called by muse, mutect2, varscan2
- HGD | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM025365, COSV52200001; called by muse, mutect2, varscan2
- HIF1A | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs760184669, COSV100048965; called by muse, mutect2, varscan2
- HIVEP1 | c.1442A>C p.K481T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101045212; called by muse, mutect2, varscan2
- HKDC1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs747283338, COSV63575537; called by muse, mutect2, varscan2
- HLA-DQA2 | c.230T>G p.F77C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100890731; called by muse, varscan2
- HMCN1 | c.10754G>A p.R3585Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.041); catalogued as rs772387252, COSV54883676, COSV99627156; called by muse, mutect2, varscan2
- HMGCR | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 44/88 reads (50%) | catalogued as COSV55315524; called by muse, mutect2, varscan2
- HMX2 | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV100378786; called by muse, mutect2, varscan2
- HNRNPAB | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100359442; called by muse, mutect2, varscan2
- HOATZ | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs750749697, COSV100239507; called by muse, mutect2, varscan2
- HORMAD2 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100374220; called by muse, mutect2, varscan2
- HOXA7 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99636527; called by muse, mutect2, varscan2
- HPS5 | c.3279G>T p.E1093D (on ENST00000349215 / NM_181507.2; = p.E979D on NM_007216.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.295); catalogued as COSV61687191; called by muse, mutect2, varscan2
- HRG | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99214848; called by muse, mutect2, varscan2
- HROB | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); catalogued as rs749407735, COSV99809277; called by muse, mutect2, varscan2
- HS2ST1 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100777767; called by muse, mutect2, varscan2
- HS6ST3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as rs762824439, COSV65006911; called by muse, mutect2, varscan2
- HSD17B11 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 28/57 reads (49%) | catalogued as rs777162512, COSV64154324; called by muse, mutect2, varscan2
- HSD17B4 | c.2168T>C p.V723A (on ENST00000414835 / NM_001199291.3; = p.V698A on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV99819905; called by muse, mutect2, varscan2
- HSD17B6 | c.643A>C p.N215H | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV100444367; called by muse, mutect2, varscan2
- HSD17B8 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100761796; called by muse, mutect2, varscan2
- HSD3B2 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs779142287, COSV101027498, COSV65593464; called by muse, mutect2, varscan2
- HTR1E | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59507859, COSV59508028; called by muse, mutect2, varscan2
- HTR4 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100088482; called by muse, mutect2, varscan2
- HTR5A | c.1050G>T p.K350N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV55283767; called by muse, varscan2
- HUWE1 | c.11977G>A p.D3993N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99472776; called by muse, mutect2, varscan2
- HUWE1 | c.9485A>G p.N3162S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99472777; called by muse, mutect2, varscan2
- HYAL4 | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99772284; called by muse, mutect2, varscan2
- HYDIN | c.12492C>A p.N4164K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV101125108; called by muse, mutect2, varscan2
- IBTK | c.2510-1G>T p.X837_splice | Splice Site (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100090920; called by muse, mutect2, varscan2
- ICE2 | c.1018C>A p.Q340K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs371898502; called by muse, varscan2
- IFT81 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV99656106; called by muse, mutect2, varscan2
- IFT88 | c.1545C>A p.F515L (on ENST00000319980 / NM_001318493.2; = p.F506L on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV100179721; called by muse, mutect2, varscan2
- IGF2BP1 | c.1629C>A p.F543L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51730165; called by muse, mutect2, varscan2
- IGF2BP3 | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV51690690, COSV99325492; called by muse, mutect2, varscan2
- IGF2R | c.5392G>T p.E1798* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV100807550; called by muse, mutect2, varscan2
- IKBKE | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1164611253, COSV100897976; called by muse, mutect2
- IL16 | c.2987C>T p.S996L (on ENST00000302987 / NM_172217.5; = p.S295L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs144988545, COSV57262018; called by muse, mutect2, varscan2
- IL17RC | c.535G>A p.A179T (on ENST00000295981 / NM_153461.4; = p.A108T on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99925075; called by muse, mutect2, varscan2
- IL1B | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV54521159; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 49/107 reads (46%) | catalogued as COSV56250744; called by muse, mutect2, varscan2
- IMPDH1 | c.547G>T p.E183* (on ENST00000470772 / NM_001142573.2; = p.E269* on NM_000883.4) | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV100118712; called by muse, mutect2, varscan2
- INPP5J | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV100459522; called by muse, mutect2, varscan2
- IQSEC2 | c.1591C>T p.R531* (on ENST00000642864 / NM_001111125.3; = p.R326* on NM_015075.2) | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100944947; called by muse, mutect2, varscan2
- IQSEC2 | c.1426G>A p.D476N (on ENST00000642864 / NM_001111125.3; = p.D271N on NM_015075.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200182557, COSV100944950; called by muse, mutect2, varscan2
- IRAK2 | c.1677G>T p.E559D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99844063; called by mutect2, varscan2
- IRAK4 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101471823; called by muse, mutect2, varscan2
- IRF8 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); catalogued as rs371942842; called by muse, mutect2, varscan2
- IRS4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.472); catalogued as COSV100929601; called by muse, mutect2, varscan2
- ISLR | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437959401, COSV51433537; called by muse, mutect2, varscan2
- ITGA3 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs759973429, COSV99143741; called by muse, mutect2, varscan2
- ITGAD | c.1666C>A p.H556N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV101210317; called by muse, mutect2, varscan2
- ITIH2 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs185942404; called by muse, mutect2, varscan2
- ITPR2 | c.4999G>T p.E1667* | Nonsense Mutation (SNP) | VAF 36/69 reads (52%) | catalogued as COSV101190030; called by muse, mutect2, varscan2
- ITPR2 | c.2530G>T p.E844* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs1400319805, COSV101190032; called by muse, mutect2, varscan2
- ITSN2 | c.1879G>T p.D627Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100743690; called by muse, mutect2, varscan2
- JAK3 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs777849274, COSV71685924; called by mutect2, varscan2
- JAKMIP1 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs866660275, COSV68952094; called by muse, mutect2, varscan2
- JAM3 | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100138245; called by muse, mutect2, varscan2
- JAM3 | c.237T>A p.F79L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100138248; called by muse, mutect2, varscan2
- JMY | c.2196G>T p.E732D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV101268041; called by muse, mutect2, varscan2
- KALRN | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs754069791, COSV53759561; called by muse, mutect2, varscan2
- KALRN | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs762826694, COSV99565101; called by muse, mutect2, varscan2
- KANK1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs751563164, COSV100619904; called by muse, mutect2
- KANSL1L | c.249G>T p.M83I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99910647; called by muse, mutect2, varscan2
- KAT2A | c.1431G>A p.T477= | Splice Region (SNP) | VAF 12/18 reads (67%) | catalogued as rs782412917, COSV99288295; called by muse, mutect2, varscan2
- KAT6A | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs371603646, COSV55905288; called by muse, mutect2, varscan2
- KAT7 | c.1614G>T p.E538D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV99371827; called by muse, mutect2, varscan2
- KATNA1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV100167841; called by muse, mutect2, varscan2
- KBTBD6 | c.1069C>A p.L357I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV101068796; called by muse, mutect2, varscan2
- KBTBD6 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV101068779; called by muse, mutect2, varscan2
- KCMF1 | c.1040T>G p.F347C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101301260; called by muse, mutect2, varscan2
- KCNAB2 | c.123C>A p.N41K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV99379168; called by muse, mutect2, varscan2
- KCNE2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs368865412, COSV51709534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH4 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs537747952, COSV52917718; called by muse, mutect2, varscan2
- KCNJ9 | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927761; called by muse, mutect2, varscan2
- KCNQ2 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV100610302; called by muse, mutect2, varscan2
- KCNQ5 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs920140431, COSV59649400, COSV59676282; called by muse, mutect2
- KCNT2 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99654455; called by muse, mutect2, varscan2
- KCNU1 | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs375926423, COSV67753019; called by muse, mutect2, varscan2
- KCTD12 | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as COSV100499734; called by muse, mutect2
- KCTD19 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV100431011; called by muse, mutect2, varscan2
- KDELR1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs770937565, COSV58102078; called by muse, mutect2, varscan2
- KDM3A | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs747738640, COSV100460592; called by muse, mutect2, varscan2
- KDR | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV99817949; called by muse, mutect2, varscan2
- KHSRP | c.597A>C p.E199D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV101231196; called by muse, varscan2
- KIAA0753 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV63819056; called by muse, mutect2, varscan2
- KIAA1109 | c.3846A>C p.E1282D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV99165484; called by muse, mutect2, varscan2
- KIAA1210 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs764922549, COSV68177845; called by muse, mutect2, varscan2
- KIAA2026 | c.6061T>G p.S2021A | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV101199090; called by muse, mutect2, varscan2
- KIAA2026 | c.3440C>A p.S1147Y | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs1169162404, COSV104430810, COSV67354027; called by muse, mutect2, varscan2
- KIF13A | c.1201A>C p.K401Q | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99436391; called by muse, mutect2, varscan2
- KIF21A | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as rs867354889, COSV100735501; called by muse, mutect2, varscan2
- KIF21B | c.1903G>A p.D635N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100144661; called by muse, mutect2, varscan2
- KIF26B | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159934380, COSV100832686; called by muse, varscan2
- KIF27 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 51/108 reads (47%) | catalogued as COSV52831679, COSV52832338; called by muse, mutect2, varscan2
- KIF5B | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV56650829; called by muse, mutect2, varscan2
- KIN | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV101092611; called by muse, mutect2, varscan2
- KL | c.2583C>A p.F861L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV101199111, COSV66307687; called by muse, mutect2, varscan2
- KLF10 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV99574804; called by muse, mutect2
- KLF17 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV100954974; called by muse, mutect2, varscan2
- KLHL1 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.145); catalogued as COSV100917486; called by muse, mutect2, varscan2
- KLHL3 | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as COSV100553305; called by muse, mutect2, varscan2
- KLHL8 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs751031930, COSV56750117; called by muse, mutect2, varscan2
- KLKB1 | c.1490-1G>T p.X497_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | catalogued as COSV99249592, COSV99250080; called by muse, mutect2, varscan2
- KLRC3 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.731); catalogued as COSV101122912; called by muse, mutect2, varscan2
- KMT2C | c.14416C>T p.R4806* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV51308724, COSV51476088; called by muse, mutect2, varscan2
- KMT2C | c.12443C>T p.P4148L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs141718495; called by muse, mutect2, varscan2
- KMT2D | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56495914; called by muse, mutect2, varscan2
- KNDC1 | c.4813C>A p.L1605M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100465205, COSV58834018; called by muse, mutect2, varscan2
- KPNA2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs782396125, COSV57856833; called by muse, mutect2, varscan2
- KRT27 | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100053286, COSV56972068; called by muse, mutect2, varscan2
- KRT77 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.234); catalogued as rs768704146, COSV59239741; called by muse, mutect2, varscan2
- LAMB4 | c.4288C>T p.R1430C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52716845; called by muse, mutect2, varscan2
- LAMP5 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV99855616; called by muse, mutect2, varscan2
- LAPTM4A | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV99442428; called by muse, mutect2, varscan2
- LARP1B | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs369019229; called by muse, mutect2, varscan2
- LATS1 | c.3045C>A p.F1015L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV53588294; called by muse, mutect2, varscan2
- LGR4 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as rs587777005, CM134877, COSV101003857; ClinVar: association; called by muse, mutect2, varscan2
- LGSN | c.1502G>T p.R501I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs753479275, COSV65727386; called by muse, mutect2, varscan2
- LHCGR | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99683816; called by muse, mutect2, varscan2
- LIAS | c.707G>T p.G236V (on ENST00000261434 / NM_001363700.2; = p.G339V on NM_006859.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99787730; called by muse, mutect2, varscan2
- LIG3 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs765117391, COSV52008011; called by muse, mutect2
- LIG4 | c.2639G>T p.R880I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100799937; called by muse, mutect2, varscan2
- LILRB2 | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as COSV100079397; called by muse, mutect2, varscan2
- LIPE | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs756437778, COSV54921047; called by muse, mutect2, varscan2
- LMO7 | c.1256G>T p.R419I (on ENST00000357063; = p.R149I on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100413395; called by muse, mutect2, varscan2
- LMX1A | c.596G>T p.R199I | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54218617, COSV99672486; called by muse, mutect2, varscan2
- LNPEP | c.944T>G p.F315C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99183546; called by muse, mutect2, varscan2
- LONP1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs370084099; called by muse, mutect2, varscan2
- LPAR1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.417); catalogued as COSV62687199; called by muse, mutect2, varscan2
- LPAR4 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs1287530585, COSV70912494; called by mutect2, varscan2
- LPCAT4 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs777544154, COSV59219729; called by muse, mutect2, varscan2
- LPO | c.1785G>T p.K595N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV51862839; called by muse, mutect2, varscan2
- LRFN2 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100599638; called by muse, mutect2, varscan2
- LRIF1 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV63896585, COSV63896696, COSV63896923; called by muse, mutect2, varscan2
- LRP1B | c.11140C>A p.L3714I | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV67185170, COSV67189807; called by muse, mutect2, varscan2
- LRP1B | c.6979G>T p.E2327* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV101257805; called by muse, mutect2, varscan2
- LRRC14 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.385); catalogued as rs760558389, COSV52879284; called by muse, mutect2, varscan2
- LRRC30 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs867925148, COSV67301336; called by muse, mutect2, varscan2
- LRRCC1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.553); catalogued as rs918214583, COSV100835489, COSV64483723; called by muse, mutect2, varscan2
- LRRK2 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs202009639, COSV54158154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRK2 | c.6544C>A p.L2182I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100110507, COSV54156156; called by muse, mutect2, varscan2
- LTBP1 | c.4609A>G p.S1537G (on ENST00000404816 / NM_206943.4; = p.S1211G on NM_000627.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV55381161, COSV55384735; called by muse, mutect2, varscan2
- LUZP2 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs543569589, COSV61221699; called by muse, mutect2, varscan2
- LUZP4 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs146024813, COSV64218395; called by muse, mutect2, varscan2
- LY6K | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs1172467075, COSV52832110; called by muse, mutect2, varscan2
- LY75 | c.4127G>A p.S1376N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV55106219, COSV99716575; called by muse, mutect2, varscan2
- MACF1 | c.9834G>T p.E3278D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV57109479; called by muse, mutect2, varscan2
- MAD2L1BP | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100938754; called by muse, mutect2, varscan2
- MAGEB1 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV100975015; called by mutect2, varscan2
- MAGEC1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV99595109; called by muse, mutect2, varscan2
- MAGEC2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs755701847, COSV55999711; called by muse, mutect2, varscan2
- MAGED2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.945); catalogued as rs779268605, COSV99514620; called by muse, mutect2, varscan2
- MAGI2 | c.42A>C p.K14N | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100834918; called by muse, mutect2, varscan2
- MAGI3 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 27/51 reads (53%) | catalogued as COSV100289457, COSV56837348; called by muse, mutect2, varscan2
- MALT1 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100618754; called by muse, mutect2, varscan2
- MAN2C1 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV51230625; called by muse, mutect2, varscan2
- MAP1B | c.2595G>T p.E865D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs559186362, COSV57097550; called by muse, mutect2, varscan2
- MAP1B | c.5254G>A p.D1752N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.158); catalogued as rs569299339, COSV57094368; called by muse, mutect2, varscan2
- MAP2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs147043359, COSV99558602; called by muse, mutect2, varscan2
- MAP3K1 | c.1567G>A p.V523I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1483289809, COSV68123901; called by muse, mutect2, varscan2
- MAP3K1 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 28/49 reads (57%) | catalogued as COSV68128615; called by muse, mutect2, varscan2
- MAP3K15 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs758936848, COSV100134933; called by muse, mutect2, varscan2
- MAP3K19 | c.3135G>T p.K1045N | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs557761734, COSV59639360; called by muse, mutect2, varscan2
- MAP6 | c.1525C>A p.H509N | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV100496744; called by muse, mutect2, varscan2
- MAP6 | c.1287G>T p.E429D | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100496745; called by muse, mutect2, varscan2
- MAPK12 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.937); catalogued as rs369173418; called by muse, mutect2, varscan2
- MARCHF10 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100248263; called by muse, mutect2, varscan2
- MARK3 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99358363; called by muse, mutect2, varscan2
- MARS1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100007440, COSV56256922; called by muse, mutect2, varscan2
- MATN3 | c.693G>T p.K231N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as CM080436, COSV101337448; called by muse, mutect2
- MBOAT2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471364240, COSV60007642; called by muse, mutect2, varscan2
- MBTPS2 | c.686T>C p.F229S | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM133524, COSV100810783; called by muse, mutect2, varscan2
- MCCC1 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as rs1432355030, COSV99659795; called by muse, mutect2, varscan2
- MCF2 | c.1847G>T p.R616I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV58477410; called by muse, mutect2, varscan2
- MCF2L2 | c.2872A>C p.N958H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.691); catalogued as COSV100192922; called by muse, mutect2, varscan2
- MCF2L2 | c.2254C>T p.L752F | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100192923; called by muse, mutect2
- MCM2 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.88); catalogued as rs745669398, COSV99413215; called by muse, mutect2, varscan2
- MCOLN2 | c.1299C>A p.F433L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52295605; called by muse, mutect2, varscan2
- MCTP1 | c.2508G>A p.W836* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV56526205; called by muse, mutect2, varscan2
- ME2 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100360807, COSV58424699; called by muse, mutect2, varscan2
- MED12L | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1056515630, COSV56382556, COSV56388879; called by muse, mutect2, varscan2
- MED12L | c.4812G>T p.K1604N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99853556; called by muse, mutect2, varscan2
- MED12L | c.5492C>A p.S1831Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV56377684; called by muse, mutect2, varscan2
- MED28 | c.291A>C p.Q97H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52847085, COSV99403766; called by muse, mutect2, varscan2
- METTL21C | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV99940055; called by muse, mutect2, varscan2
- MEX3B | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1256978656, COSV61663338; called by muse, mutect2, varscan2
- MFN1 | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as rs1440003040, COSV99764511; called by muse, mutect2
- MGAM | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778528944, COSV72073567; called by muse, mutect2, varscan2
- MGARP | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 43/98 reads (44%) | catalogued as rs979932451, COSV101299218, COSV67449217; called by muse, mutect2, varscan2
- MIA3 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60510777; called by muse, mutect2, varscan2
- MICAL2 | c.5867G>A p.R1956K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56284705; called by muse, mutect2, varscan2
- MKI67 | c.7747A>C p.K2583Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.494); catalogued as COSV100896659; called by muse, mutect2, varscan2
- MMP8 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779074177, CM124469, COSV52633508; called by muse, mutect2, varscan2
- MMS22L | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs751871617, COSV51516916; called by muse, mutect2, varscan2
- MNS1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV53067574; called by muse, mutect2, varscan2
- MOGAT2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs745626864, COSV99549607; called by muse, varscan2
- MORC1 | c.2006G>T p.R669I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99226497; called by muse, mutect2, varscan2
- MOSPD2 | c.1346A>C p.K449T | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); catalogued as rs759364943, COSV100996823; called by muse, mutect2, varscan2
- MOV10 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1271000315, COSV100659618; called by muse, mutect2, varscan2
- MOXD1 | c.1363T>C p.W455R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100381660; called by muse, mutect2, varscan2
- MOXD1 | c.505T>G p.L169V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100381664; called by muse, mutect2
- MPP5 | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as COSV99907152; called by muse, mutect2, varscan2
- MRO | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99838840; called by muse, mutect2, varscan2
- MROH2B | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV101270736, COSV68186729; called by muse, mutect2, varscan2
- MROH5 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV101436024; called by muse, mutect2
- MT2A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs149120520, COSV99803283; called by muse, mutect2, varscan2
- MTHFD1L | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.828); catalogued as rs377525704; called by muse, mutect2, varscan2
- MTMR12 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV99373680; called by muse, mutect2, varscan2
- MTPAP | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as rs759555857, COSV53931493; called by muse, mutect2, varscan2
- MTSS1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as COSV61495501; called by muse, mutect2, varscan2
- MTTP | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.782); catalogued as rs769611449, COSV55508563; called by muse, mutect2, varscan2
- MTUS2 | c.1588C>A p.L530I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV101462271; called by muse, mutect2
- MUC16 | c.12148G>T p.E4050* | Nonsense Mutation (SNP) | VAF 28/97 reads (29%) | catalogued as COSV101200191, COSV67457335; called by muse, mutect2, varscan2
- MUC17 | c.1514C>A p.T505N | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV100073782; called by muse, mutect2, varscan2
- MUC21 | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs753368195, COSV66222122; called by muse, mutect2, varscan2
- MUC7 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100512329; called by mutect2, varscan2
- MXRA5 | c.4156G>A p.A1386T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99477437; called by muse, mutect2, varscan2
- MXRA5 | c.3973G>T p.E1325* | Nonsense Mutation (SNP) | VAF 31/62 reads (50%) | catalogued as COSV54231988, COSV99477442; called by muse, mutect2, varscan2
- MXRA5 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs746524869, COSV99477446; called by muse, mutect2, varscan2
- MYBPC1 | c.1983A>T p.K661N (on ENST00000550270 / NM_206820.2; = p.K686N on NM_002465.4) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100638087; called by muse, mutect2, varscan2
- MYH6 | c.3324G>T p.K1108N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs727505164, COSV100676691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.2260G>T p.D754Y | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487300978, COSV100676692; called by muse, mutect2, varscan2
- MYH7 | c.3318G>T p.K1106N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs575577624, COSV100806228; called by muse, mutect2, varscan2
- MYH8 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV67968964; called by muse, mutect2, varscan2
- MYL10 | c.540A>C p.K180N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV56208019; called by muse, mutect2, varscan2
- MYLK2 | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101044820; called by muse, mutect2, varscan2
- MYO15A | c.3734G>T p.R1245I | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99233210; called by muse, mutect2, varscan2
- MYO16 | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV51792118, COSV99194029; called by muse, mutect2, varscan2
- MYO1E | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.3); PolyPhen benign (0.119); catalogued as COSV99895825; called by muse, mutect2, varscan2
- MYO1G | c.1791C>A p.F597L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV99348806; called by muse, mutect2, varscan2
- MYO3A | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752594701, COSV56327010; called by mutect2, varscan2
- MYOM3 | c.4120C>T p.P1374S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.216); catalogued as COSV100141780; called by muse, mutect2, varscan2
- MYOM3 | c.2932G>T p.E978* | Nonsense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as COSV100293045; called by muse, mutect2, varscan2
- MYPN | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV62734252; called by muse, mutect2, varscan2
- NAA16 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101038366; called by muse, mutect2, varscan2
- NAALAD2 | c.1887C>A p.F629L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV58959962; called by muse, mutect2
- NBEA | c.3001C>T p.R1001* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV59803480; called by muse, mutect2, varscan2
- NBEA | c.5128G>A p.E1710K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as rs561239166, COSV59766532; called by muse, mutect2, varscan2
- NCAM2 | c.1350G>T p.K450N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53089173; called by muse, mutect2, varscan2
1,030 further variants in this file (652 protein-altering or splice-affecting, 337 silent, 41 other) are not listed here.
